Surgical pathology report (de-identified scan), TCGA case TCGA-ZL-A9V6, project TCGA-THYM (Thymoma), tissue source site Valley Hospital, specimen TCGA-ZL-A9V6-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

SPECIMEN INQUIRY REPORT

Name: [REDACTED] Attend Dr: [REDACTED]
Acct#: [REDACTED] Unit#: [REDACTED]
Diag: [REDACTED]

Received:
Service Date:

Subm. Dr: [REDACTED]

Spec#: [REDACTED]

CLINICAL DIAGNOSIS:

Thymoma, Clinically Stage 1

SOURCE OF SPECIMEN:

Thymus Gland

PATHOLOGIC DIAGNOSIS:

THYMUS GLAND: THYMUS GLAND SHOWING MIXED LYMPHOEPITHELIAL THYMOMA (TYPE AB) WITH PROMINENT CYST FORMATION.

THE TUMOR IS REPORTED TO HAVE MEASURED 4.2 X 3 CM BY IMAGING.

THE INKED MARGINS OF RESECTION ARE HISTOLOGICALLY CLEAR.

TUMOR MICROFOCALLY COMES TO APPROXIMATELY 2 MM FROM THE INKED EXTERNAL SURFACE OF THE SPECIMEN AT ITS NEAREST POINT.

BACKGROUND HISTOLOGICALLY UNREMARKABLE ATROPHIC THYMIC TISSUE.

NOTE: Immunostains for broad spectrum cytokeratin, synaptophysin and chromogranin (the latter two stains both negative) were used to evaluate the specimen. Flow cytometry reveals a benign, T-cell dominant lymphoid population with no antigenic aberrancies. The minority B-cell population is polyclonal.

Examination and Report by: [REDACTED]

ICD9: 164.0

CPT: 88329, 88307, 88342 x 3, 88188

DICTATED:

TRANSCRIBED:

MICROSCOPIC DESCRIPTION:

Sections reveal a mixed lymphoepithelial thymoma (type AB) with prominent areas of cyst formation. The epithelial component of the lesion is composed of bland cells

** CONTINUED ON NEXT PAGE **

ICD-0.3
Thymoma, type AB^{NOs} 8582/3
Site: Thymus C379
JW 5/28/14

[page 2 of 3]
SPECIMEN INQUIRY REPORT

Patient: [REDACTED]

(Continued...)

Received:

Specimen #: [REDACTED]

(Continued)

MICROSCOPIC DESCRIPTION: (Continued)

with scanty cytoplasm and monotonously uniform short spindled nuclei with evenly distributed chromatin, small to absent nucleoli and no appreciable mitotic activity. They are generally arranged in a patternless fashion, but in focal areas, vague whorls may be seen. Scattered small foci of glandular differentiation composed of cells with similar morphologic characteristics well oriented around luminal spaces or occasionally around the perimeters of micropapillary formations. A small inconspicuous population of lymphocytes is scattered about. The lymphoid component represents approximately 20 to 25% of the cellular elements. It shows focal germinal center formation and generally small aggregates of cytokeratin positive epithelial cells which are not readily apparent on H&E stained sections. The inked external surfaces of the specimen are histologically clear. Tumor microfocally comes to within 2 mm of the inked surface in block 1. Atrophic histologically unremarkable thymic tissue is present in the background.

MACROSCOPIC DESCRIPTION:

The specimen is identified on the requisition slip and specimen container as "thymus gland". Received fresh for operating room examination is an irregularly shaped yellow-tan thymus gland weighing 96 grams and measuring 20 x 5 x 3 cm. The specimen is inked and sectioned revealing the presence of a partially cystic firm-tan mass measuring 3.8 cm in greatest dimension, located at one pole of the unoriented specimen. The remainder of the specimen is composed primarily of glossy yellow soft tissue. A portion of the cystic mass is submitted for tumor banking and a portion is submitted for flow cytometry. Representative sections are submitted as follows:

SECTION CODE:

- 1 through 4 - contain the cystic mass and surrounding area
- 5 through 8 - representative sections of grossly uninvolved thymus

OPERATING ROOM EXAMINATION: APPROXIMATELY 4 CM PARTIALLY CYSTIC MASS AT ONE POLE OF RESECTED THYMUS GLAND MEASURING 20 X 5 X 3 CM. PORTION SUBMITTED FOR TUMOR BANK.

[REDACTED]
DICTATED:

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
Department of Pathology -

SPECIMEN INQUIRY REPORT

Patient: [REDACTED]

(Continued...)

Received:

Specimen [REDACTED]

(Continued)

FLOW CYTOMETRY IMMUNOPHENOTYPING

DATE:

CLINICAL DATA: [REDACTED]

DESCRIPTION: A thymus gland was submitted for immunophenotyping.

CD45 vs. side scatter showed the lymphocytic population to comprise 88.1% of the cellular elements. The lymphocytes are T-cell dominant. The T-cells show no antigenic aberrancies. The CD4/8 ratio is 2.1%. 6.2% show characteristic co-expression of CD4 and CD8. The minority B-cell population (CD19=17.9% and CD20=18.3%) is polyclonal (skappa=8.5% and slambda=8.1%).

IMPRESSION: POPULATION OF NORMAL THYMIC LYMPHOCYTES.

Examination and Report by: [REDACTED] MD

<Electronically Signed> by [REDACTED]

** END OF REPORT **

Source: NCI Genomic Data Commons file 4529b841-a4b5-4541-b326-3cd42508ef87 (TCGA-ZL-A9V6.6096FD4A-5F13-4A71-BB63-34432CCCE3CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).